Gene-level copy-number profile of tumor specimen TCGA-RP-A693-06A from TCGA case TCGA-RP-A693, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.7 years (28,394 days).
Specimen TCGA-RP-A693-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.eef6eec8-7b32-457a-92df-6a2fc2d08379.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RP-A693-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/497b5392-b62e-4b44-b451-5e2df67d61cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 7,654; copy number 2: 49,343; copy number 3: 2,788.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RP-A693-06A-13D-A30W-01): tumor purity 0.32, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:124,770,123–125,707,234, 24 genes (within-gene range 0–2): AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP, AL359632.1, MAPKAP1, RN7SL30P, AL162584.1.
- chr10:87,751,512–88,584,530, 11 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
